Somatic mutation profile of cancer-model specimen HCM-SANG-0272-C20-85A (3D Organoid; aliquot HCM-SANG-0272-C20-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0272-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0272-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc93b93b-417b-46bf-802c-ac697c8948e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0272-C20-10A (Blood Derived Normal), aliquot HCM-SANG-0272-C20-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62c22e25-5be1-4a86-ad79-d769158fe155

The open-access MAF lists 107 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Frame Shift Del 7, In Frame Del 5, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARX | c.428_451del p.G143_A150del | In Frame Del (DEL) | VAF 254/365 reads (70%) | catalogued as rs387906493; ClinVar: uncertain significance / pathogenic; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 89/275 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.537T>A p.H179Q | Missense Mutation (SNP) | VAF 232/232 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs876660821, CM0910925, COSV52669519, COSV52673406, COSV53016879; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 332/481 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs375519291; called by muse, mutect2, varscan2
- ACHE | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 195/596 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1430893148, COSV53815616; called by muse, mutect2, varscan2
- ARHGAP20 | c.630C>T p.Y210= | Splice Region (SNP) | VAF 66/334 reads (20%) | catalogued as rs771316747, COSV52818215; called by muse, mutect2, varscan2
- ATRX | c.7393G>A p.G2465S | Missense Mutation (SNP) | VAF 282/283 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs782020537; called by muse, mutect2, varscan2
- CECR2 | c.3386C>T p.T1129M (on ENST00000342247 / NM_001290047.2; = p.T945M on NM_001290046.1) | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777432282, COSV52837111; called by muse, mutect2, varscan2
- CNTN6 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 119/383 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as rs866963872, COSV63169825; called by muse, mutect2, varscan2
- COL5A1 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 261/411 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257715072, COSV100880665; called by muse, mutect2, varscan2
- DYSF | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 177/351 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs755046419, COSV50629903; called by muse, mutect2, varscan2
- E2F7 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs762356959, COSV59737409; called by muse, mutect2, varscan2
- ESPL1 | c.4699G>A p.V1567I | Missense Mutation (SNP) | VAF 102/328 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1041631661; called by muse, mutect2
- EYS | c.7205G>T p.R2402M | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as CM104444; called by muse, mutect2, varscan2
- FOXE1 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 219/698 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746677097; called by muse, mutect2, varscan2
- GRIN2A | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 175/508 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs758742694; called by muse, mutect2, varscan2
- GULP1 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100770043; called by muse, mutect2, varscan2
- KCNMB1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 272/554 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs773550380, COSV51131735; called by muse, mutect2, varscan2
- LRRN4CL | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 385/644 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54017816; called by muse, mutect2, varscan2
- MATN4 | c.1532C>T p.A511V (on ENST00000372754; = p.A470V on NM_003833.4) | Missense Mutation (SNP) | VAF 505/722 reads (70%) | PolyPhen benign (0.366); catalogued as rs771701454; called by muse, mutect2, varscan2
- MEGF8 | c.6016C>T p.R2006W (on ENST00000251268 / NM_001271938.2; = p.R1939W on NM_001410.3) | Missense Mutation (SNP) | VAF 259/420 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs762333959, COSV99238611; called by muse, mutect2, varscan2
- NOL11 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs1041219889, COSV53525630; called by muse, mutect2, varscan2
- NSRP1 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.513); catalogued as COSV55933144; called by muse, mutect2, varscan2
- OR2T2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 91/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61618302; called by muse, mutect2, varscan2
- PCLO | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.997); catalogued as COSV61637126; called by muse, mutect2, varscan2
- RASAL1 | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 58/599 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs954944392, COSV55659370; called by muse, mutect2
- RBM10 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 340/649 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV61313291; called by muse, mutect2, varscan2
- RET | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs762952212, COSV60703707; ClinVar: uncertain significance; called by muse, varscan2
- RIPK3 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs753874743, COSV53474494; called by muse, mutect2, varscan2
- SSR1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs747697031; called by muse, mutect2, varscan2
- STARD13 | c.686G>T p.S229I (on ENST00000336934 / NM_001243476.3; = p.S111I on NM_052851.3) | Missense Mutation (SNP) | VAF 432/1245 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55230010; called by muse, mutect2, varscan2
- TERF2 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 268/436 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs779198488; called by muse, mutect2, varscan2
- TNXB | c.7171G>A p.E2391K (on ENST00000647633; = p.E2144K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/697 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs1413060979; called by muse, mutect2, varscan2
- TRIM3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 190/620 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as rs561735237, COSV61985571; called by muse, mutect2, varscan2
- WNT11 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 597/737 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1218682764, COSV59443089; called by muse, mutect2, varscan2
- ZNF790 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 188/291 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs745538231; called by muse, mutect2, varscan2
- AACS | c.882_890del p.G295_P297del | In Frame Del (DEL) | VAF 43/479 reads (9%) | called by mutect2, pindel
- ABHD11 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 255/361 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ADAM29 | c.2277T>A p.S759R | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.164); called by mutect2, varscan2
- AGK | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ANK2 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 117/248 reads (47%) | called by muse, mutect2, varscan2
- AOC2 | c.1756del p.A586Lfs*45 (on ENST00000253799 / NM_009590.4; = p.A586Lfs*18 on NM_001158.5) | Frame Shift Del (DEL) | VAF 82/852 reads (10%) | called by mutect2, pindel
- APC | c.4393_4394dup p.S1465Rfs*9 | Frame Shift Ins (INS) | VAF 218/232 reads (94%) | called by mutect2, varscan2
- ATIC | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 176/314 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC6 | c.383T>G p.F128C | Missense Mutation (SNP) | VAF 153/269 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC141 | c.4309_4314del p.E1437_P1438del | In Frame Del (DEL) | VAF 23/237 reads (10%) | called by mutect2, pindel
- CCPG1 | c.1288A>G p.R430G | Missense Mutation (SNP) | VAF 309/310 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL20A1 | c.3184T>C p.S1062P | Missense Mutation (SNP) | VAF 198/720 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, varscan2
- DDX46 | c.1001A>C p.N334T | Missense Mutation (SNP) | VAF 150/274 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- DENND4B | c.491T>G p.L164R | Missense Mutation (SNP) | VAF 299/679 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DGKH | c.1931T>G p.V644G | Missense Mutation (SNP) | VAF 25/435 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2
- DHX15 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM83B | c.1691C>G p.S564* | Nonsense Mutation (SNP) | VAF 136/380 reads (36%) | called by muse, mutect2, varscan2
- FAT3 | c.6225A>C p.E2075D | Missense Mutation (SNP) | VAF 220/604 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FBXO45 | c.410_416del p.I137Rfs*32 | Frame Shift Del (DEL) | VAF 48/540 reads (9%) | called by mutect2, pindel
- FGFR2 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 221/318 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLII | c.3730_3738del p.L1244_R1246del | In Frame Del (DEL) | VAF 70/476 reads (15%) | called by mutect2, pindel, varscan2
- FLNA | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- HERC2 | c.9603del p.R3201Sfs*2 | Frame Shift Del (DEL) | VAF 66/610 reads (11%) | called by mutect2, pindel, varscan2
- HGF | c.1397T>C p.I466T | Missense Mutation (SNP) | VAF 167/268 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- HOXA10 | c.359del p.D120Afs*137 | Frame Shift Del (DEL) | VAF 88/824 reads (11%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 422/1118 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KCNH1 | c.2491del p.C831Vfs*44 (on ENST00000271751 / NM_172362.3; = p.C804Vfs*44 on NM_002238.4) | Frame Shift Del (DEL) | VAF 323/837 reads (39%) | called by mutect2, pindel, varscan2
- KIF18A | c.2495A>C p.K832T | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LHB | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 281/444 reads (63%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGEB4 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 62/750 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.285); called by muse, mutect2
- MTFR2 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 145/239 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MUC16 | c.8642_8664del p.P2881Hfs*5 | Frame Shift Del (DEL) | VAF 132/244 reads (54%) | called by mutect2, pindel, varscan2
- NALCN | c.3874T>A p.F1292I | Missense Mutation (SNP) | VAF 161/600 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NBEAL2 | c.968T>A p.L323Q | Missense Mutation (SNP) | VAF 194/316 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- NFATC3 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 185/270 reads (69%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- NOTCH4 | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 229/350 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T35 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 108/412 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PMF1-BGLAP | c.551_552del p.V184Afs*8 | Frame Shift Del (DEL) | VAF 38/386 reads (10%) | called by mutect2, pindel, varscan2
- RNF165 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 365/366 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by mutect2, varscan2
- SLITRK2 | c.2429G>T p.C810F | Missense Mutation (SNP) | VAF 335/336 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRPN | c.235T>A p.S79T | Missense Mutation (SNP) | VAF 331/331 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- TBC1D32 | c.2471_2479del p.T824_V826del | In Frame Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- TGFBR1 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, varscan2
- TPX2 | c.2097G>T p.Q699H | Missense Mutation (SNP) | VAF 327/723 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ZFP92 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 513/514 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZNF121 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ZNF674 | c.1640A>C p.H547P | Missense Mutation (SNP) | VAF 247/484 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP58 | c.2613G>A p.T871= | Silent (SNP) | VAF 64/269 reads (24%) | catalogued as rs370337063; called by muse, mutect2, varscan2
- COL15A1 | c.1626T>C p.A542= | Silent (SNP) | VAF 279/422 reads (66%) | called by muse, mutect2, varscan2
- CRYBG2 | c.2691C>G p.G897= | Silent (SNP) | VAF 336/681 reads (49%) | called by muse, mutect2, varscan2
- CYP2D7 | c.270G>A p.A90= | Silent (SNP) | VAF 190/776 reads (24%) | catalogued as rs1460805293; called by muse, mutect2
- DSCAM | c.4656C>T p.N1552= | Silent (SNP) | VAF 216/447 reads (48%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.384A>G p.E128= | Silent (SNP) | VAF 83/162 reads (51%) | called by muse, mutect2, varscan2
- FBXL6 | c.960C>G p.V320= | Silent (SNP) | VAF 669/917 reads (73%) | called by muse, mutect2, varscan2
- FHOD3 | c.1056C>T p.G352= | Silent (SNP) | VAF 484/484 reads (100%) | catalogued as rs142186343; called by muse, mutect2, varscan2
- FSIP2 | c.20265C>T p.A6755= | Silent (SNP) | VAF 40/394 reads (10%) | called by muse, mutect2
- MEDAG | c.630C>T p.L210= | Silent (SNP) | VAF 133/486 reads (27%) | called by muse, mutect2, varscan2
- PRR14 | c.1566A>G p.E522= | Silent (SNP) | VAF 330/493 reads (67%) | called by muse, varscan2
- RTL9 | c.1113G>A p.A371= | Silent (SNP) | VAF 298/299 reads (100%) | catalogued as rs1474896375, COSV71825796, COSV71826158; called by muse, mutect2, varscan2
- SAP25 | c.426G>A p.E142= (on ENST00000538735; = p.E240= on NM_001168682.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 213/667 reads (32%) | called by muse, mutect2, varscan2
- SIM1 | c.15C>A p.S5= | Silent (SNP) | VAF 177/278 reads (64%) | called by muse, mutect2, varscan2
- SPEG | c.2394C>T p.N798= | Silent (SNP) | VAF 373/674 reads (55%) | catalogued as rs1356443986; called by muse, mutect2, varscan2
- SPHKAP | c.1770G>A p.P590= | Silent (SNP) | VAF 181/422 reads (43%) | catalogued as rs141688278; called by muse, mutect2, varscan2
- TESC | c.477C>T p.D159= | Silent (SNP) | VAF 139/431 reads (32%) | catalogued as rs572866908; called by muse, mutect2, varscan2
- TPGS1 | c.744G>A p.G248= | Silent (SNP) | VAF 232/628 reads (37%) | called by muse, mutect2, varscan2
- TRIM69 | c.1320C>T p.L440= (on ENST00000329464 / NM_182985.5; = p.L281= on NM_080745.5) | Silent (SNP) | VAF 400/401 reads (100%) | catalogued as rs778145986; called by muse, mutect2, varscan2
- ZFAT | c.2571C>T p.S857= | Silent (SNP) | VAF 118/578 reads (20%) | called by muse, mutect2, varscan2
- ZNF423 | c.2178G>T p.V726= (on ENST00000563137 / NM_001379286.1; = p.V718= on NM_015069.4) | Silent (SNP) | VAF 107/379 reads (28%) | called by muse, mutect2, varscan2
- ZNF99 | c.984T>C p.L328= | Silent (SNP) | VAF 39/360 reads (11%) | called by muse, mutect2, varscan2
- TENM4 | c.*893A>G | 3'UTR (SNP) | VAF 236/576 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.10360+2523T>C | Intron (SNP) | VAF 138/334 reads (41%) | called by muse, mutect2, varscan2
